Somatic mutation profile of tumor specimen TCGA-KM-8438-01A (aliquot TCGA-KM-8438-01A-11D-2310-10) from TCGA case TCGA-KM-8438, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 45.7 years (16,683 days).
Specimen TCGA-KM-8438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf1c4454-518c-4356-b8d2-2440135bc587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8438-10A (Blood Derived Normal), aliquot TCGA-KM-8438-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6c01fa5-4a07-4b15-b3e1-7ed59ccafbc5

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Frame Shift Del 4, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSK | c.1148del p.P383Rfs*22 | Frame Shift Del (DEL) | VAF 48/84 reads (57%) | catalogued as COSV101187566; called by mutect2, pindel, varscan2
- CRHR2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs548065920, COSV100793251; called by muse, mutect2, varscan2
- DGKQ | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs765262723; called by muse, mutect2, varscan2
- GCC1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.184); catalogued as COSV99133696; called by muse, mutect2, varscan2
- LILRB5 | c.1502C>T p.A501V (on ENST00000449561 / NM_001081442.3; = p.A500V on NM_006840.5) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs762519162, COSV100300805, COSV60258408; called by muse, mutect2, varscan2
- MICU3 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs150021056; called by muse, mutect2, varscan2
- NFATC1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139150912, COSV53706137; called by muse, mutect2, varscan2
- PMM1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs773911507; called by muse, mutect2, varscan2
- SETD2 | c.7195C>T p.R2399* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV57435779; called by muse, mutect2, varscan2
- TBC1D10C | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100408259; called by muse, mutect2
- TTN | c.5582G>A p.R1861H (on ENST00000591111; = p.R1815H on NM_003319.4) | Missense Mutation (SNP) | VAF 116/155 reads (75%) | PolyPhen probably damaging (0.998); catalogued as rs140914855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VMP1 | c.972del p.I324Mfs*7 | Frame Shift Del (DEL) | VAF 16/153 reads (10%) | catalogued as COSV51873041; called by mutect2, pindel, varscan2
- WNK3 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs959075562, COSV100671570; called by muse, mutect2
- ZAN | c.4760A>C p.N1587T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs754496121; called by muse, mutect2, varscan2
- ATP11B | c.3365G>T p.C1122F | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- HNF1A | c.574dup p.D192Gfs*2 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- ITGA9 | c.2335C>A p.P779T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LMOD2 | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RMDN1 | c.789_792del p.L263Ffs*3 | Frame Shift Del (DEL) | VAF 62/168 reads (37%) | called by pindel, varscan2
- SLC4A2 | c.3459_3462del p.Y1154Sfs*59 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- SQOR | c.184dup p.M62Nfs*14 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | called by pindel, varscan2
- ZNF837 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH9 | c.11883T>C p.I3961= | Silent (SNP) | VAF 24/36 reads (67%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.357C>T p.R119= | Silent (SNP) | VAF 67/245 reads (27%) | catalogued as COSV99707590; called by muse, mutect2, varscan2
- SYT9 | c.492G>A p.S164= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs766198197, COSV59625597; called by muse, mutect2, varscan2
- XKR7 | c.954G>A p.A318= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs375135448; called by muse, mutect2, varscan2
